Somatic mutation profile of tumor specimen TCGA-B0-5109-01A (aliquot TCGA-B0-5109-01A-02D-1421-08) from TCGA case TCGA-B0-5109, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G4; Age at diagnosis: 69.6 years (25,428 days).
Specimen TCGA-B0-5109-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 087fa040-c0aa-4e27-960b-ea3ba610e3a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5109-11A (Solid Tissue Normal), aliquot TCGA-B0-5109-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1995873f-eab1-4826-801a-a2363e038a40

The open-access MAF lists 49 somatic variants for this specimen: 40 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 4, Nonsense Mutation 4, Frame Shift Del 3, RNA 3, Splice Site 2, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA2 | c.3682G>T p.G1228W (on ENST00000614293; = p.G1198W on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55804647; called by muse, varscan2
- ANO4 | c.2302G>C p.G768R (on ENST00000392977 / NM_001286615.2; = p.G733R on NM_178826.4) | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54606843; called by muse, varscan2
- ATF7IP2 | c.685G>T p.V229F | Missense Mutation (SNP) | VAF 43/182 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as COSV61094739; called by muse, mutect2, varscan2
- CCNJL | c.1226C>G p.P409R | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV57446065, COSV99979866; called by muse, mutect2, varscan2
- CHD7 | c.8450A>G p.N2817S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.045); catalogued as COSV71107481, COSV71111544; called by muse, mutect2, varscan2
- CLCN2 | c.2642G>A p.R881H | Missense Mutation (SNP) | VAF 54/156 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs199616806, COSV55603227; called by muse, mutect2, varscan2
- CLVS1 | c.47G>T p.W16L | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.037); catalogued as COSV57980121; called by muse, mutect2, varscan2
- CSE1L | c.371C>A p.P124Q | Missense Mutation (SNP) | VAF 46/218 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1334983529, COSV53703338, COSV53704003; called by muse, mutect2, varscan2
- CSGALNACT2 | c.1030A>G p.N344D | Missense Mutation (SNP) | VAF 7/157 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.318); catalogued as COSV65676175; called by muse, mutect2
- CSPG4 | c.4075C>G p.P1359A | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV57899471; called by muse, mutect2, varscan2
- DDX28 | c.1334A>G p.K445R | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV60105997; called by muse, mutect2, varscan2
- DNAH2 | c.8188G>A p.V2730M | Missense Mutation (SNP) | VAF 51/281 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs776393739, COSV66723550; called by muse, mutect2, varscan2
- FGFR3 | c.986C>A p.S329* | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | catalogued as COSV53412627; called by muse, mutect2, varscan2
- FKBP6 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 44/209 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as rs1216896736, COSV52719022; called by muse, mutect2, varscan2
- GBA3 | c.1229A>G p.N410S | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs556093396, COSV72438435, COSV72438489; called by muse, mutect2, varscan2
- GPR162 | c.1415A>T p.E472V (on ENST00000311268 / NM_019858.2; = p.E188V on NM_014449.2) | Missense Mutation (SNP) | VAF 65/168 reads (39%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.348); catalogued as COSV51835224; called by muse, mutect2, varscan2
- HECTD2 | c.1849G>A p.V617I | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.807); catalogued as COSV53223677; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.712C>A p.R238S (on ENST00000354667 / NM_031243.3; = p.R226S on NM_002137.4) | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV61160567, COSV61161142; called by muse, mutect2, varscan2
- IL17RC | c.643G>T p.V215L (on ENST00000295981 / NM_153461.4; = p.V144L on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.535); catalogued as COSV55969795; called by muse, mutect2, varscan2
- ILDR2 | c.552G>A p.M184I | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54833989; called by muse, mutect2, varscan2
- IPO7 | c.1280G>A p.R427Q | Missense Mutation (SNP) | VAF 44/203 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.762); catalogued as rs779833967, COSV63352630; called by muse, mutect2, varscan2
- LUM | c.60C>G p.Y20* | Nonsense Mutation (SNP) | VAF 23/121 reads (19%) | catalogued as COSV57128862; called by muse, mutect2, varscan2
- MAP7 | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63421921; called by muse, mutect2, varscan2
- MYCBP2 | c.2474G>C p.R825P (on ENST00000357337; = p.R863P on NM_015057.5) | Missense Mutation (SNP) | VAF 42/251 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.146); catalogued as COSV62027764, COSV62032014; called by muse, mutect2, varscan2
- MYH7 | c.3288T>A p.D1096E | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV62522028; called by muse, mutect2, varscan2
- NPHP3 | c.1986-1G>T p.X662_splice | Splice Site (SNP) | VAF 80/230 reads (35%) | catalogued as COSV58632258; called by mutect2, varscan2
- OMD | c.1162G>T p.D388Y | Missense Mutation (SNP) | VAF 55/171 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.62); catalogued as COSV65020399; called by muse, mutect2, varscan2
- PCDHGB3 | c.589A>T p.K197* | Nonsense Mutation (SNP) | VAF 26/161 reads (16%) | catalogued as COSV54001400; called by muse, mutect2, varscan2
- PRKAG2 | c.1388T>G p.V463G | Missense Mutation (SNP) | VAF 32/213 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55236650; called by muse, mutect2, varscan2
- SOX9 | c.703C>G p.P235A | Missense Mutation (SNP) | VAF 84/326 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV55427034, COSV55427074; called by muse, mutect2, varscan2
- SPHKAP | c.4210G>C p.E1404Q | Missense Mutation (SNP) | VAF 58/225 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV60871010, COSV60889520; called by muse, mutect2, varscan2
- SPTAN1 | c.1764G>C p.W588C | Missense Mutation (SNP) | VAF 89/228 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63988988; called by muse, mutect2, varscan2
- TPRX1 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as rs759338638, COSV59116855; called by muse, mutect2
- TRIOBP | c.5638G>T p.E1880* (on ENST00000644935 / NM_001039141.3; = p.E167* on NM_007032.5) | Nonsense Mutation (SNP) | VAF 11/58 reads (19%) | catalogued as COSV58526141; called by muse, mutect2, varscan2
- ZNF670 | c.4-1G>A p.X2_splice | Splice Site (SNP) | VAF 18/97 reads (19%) | catalogued as COSV100829323, COSV63608638; called by muse, mutect2, varscan2
- ZSCAN21 | c.1187G>A p.S396N | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as COSV52851845; called by muse, mutect2, varscan2
- PRAMEF19 | c.769G>T p.A257S | Missense Mutation (SNP) | VAF 112/409 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- PTGER4 | c.1465_1466del p.*489Ifs*47 | Frame Shift Del (DEL) | VAF 27/155 reads (17%) | called by pindel, varscan2
- VPS13A | c.3346del p.Y1116Ifs*27 | Frame Shift Del (DEL) | VAF 36/168 reads (21%) | called by mutect2, pindel, varscan2
- ZNF180 | c.433del p.D145Mfs*57 | Frame Shift Del (DEL) | VAF 125/482 reads (26%) | called by mutect2, pindel, varscan2
- ARID4A | c.2745A>C p.I915= | Silent (SNP) | VAF 40/147 reads (27%) | catalogued as COSV62165628, COSV62167049; called by muse, mutect2, varscan2
- PI4KB | c.822C>T p.R274= (on ENST00000368873 / NM_001369623.1; = p.R286= on NM_002651.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 64/280 reads (23%) | catalogued as COSV55020167; called by muse, mutect2, varscan2
- PODXL | c.819G>A p.S273= (on ENST00000378555 / NM_001018111.3; = p.S241= on NM_005397.4) | Silent (SNP) | VAF 42/236 reads (18%) | catalogued as rs753882206, COSV59872060; called by muse, mutect2, varscan2
- SLC39A6 | c.2247C>T p.I749= | Silent (SNP) | VAF 41/202 reads (20%) | catalogued as rs747730811, COSV52367880; called by muse, mutect2, varscan2
- AL353804.6 | n.94G>T | RNA (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2
- NRP1 | c.981+4504C>G | Intron (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- STAG3L2 | n.687G>A | RNA (SNP) | VAF 28/241 reads (12%) | called by muse, mutect2, varscan2
- TRIM36 | c.63+2143G>A | Intron (SNP) | VAF 30/179 reads (17%) | catalogued as rs768043116, COSV56692067; called by muse, mutect2, varscan2
- UBTFL2 | n.816T>C | RNA (SNP) | VAF 19/86 reads (22%) | catalogued as rs749092684; called by muse, mutect2, varscan2
